Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01D, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01D-01A (Primary Tumor).

TCGA #:

Sample ID #

Diagnosis:

Resected section of colon (rectosigmoid) with an ulcerated colon carcinoma characterized histologically as a poorly differentiated, partially mucinous adenocarcinoma of the colorectal type, extending a max of 10 cm to a resection margin, and measuring a maximum of 2.5 cm in diameter at the widest point. Invasive spread of the tumor within all intestinal wall layers to the neighboring mesocolic fatty tissue. Numerous lymphatic processes in the region of the tumor margin. The remaining intestinal wall has no relevant pathological findings; in particular, no evidence of pseudodiverticula.

Tumor-free oral and aboral resection margin.

12 local lymph nodes with metastases of the rectal carcinoma partly transgressing the lymph node capsules.

Stage of tumor: pT3, pN2 (12/12) L1 V0; G3 R0

ICD-O-3

Adenocarcinoma, mucinous, nos 8480/3

Site: Rectosigmoid, colon C19.9 w 3/30/11

Reviewer (initials)	RMT	5/16/11

Source: NCI Genomic Data Commons file 38852d99-9cf5-4ef3-bcea-b4def27e51ea (TCGA-AA-A01D.B52F7D2A-2177-4A2A-A941-042D661D3F37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).